Somatic mutation profile of tumor specimen TCGA-CE-A482-01A (aliquot TCGA-CE-A482-01A-11D-A23U-08) from TCGA case TCGA-CE-A482, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 27.9 years (10,192 days).
Specimen TCGA-CE-A482-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82c3920e-47b7-475b-988e-d5ba52f14fe1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CE-A482-10A (Blood Derived Normal), aliquot TCGA-CE-A482-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abbb66c5-1bad-4a7a-8454-2440a59d28ad

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRGUK | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53643722; called by muse, mutect2, varscan2
- TCEAL6 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.801); catalogued as COSV65654281; called by muse, mutect2, varscan2
- ADGRA3 | c.243C>T p.N81= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV57552141; called by muse, mutect2, varscan2
- DIP2C | c.3660C>A p.A1220= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV55145025, COSV55179007; called by muse, mutect2, varscan2
- RAF1 | c.798C>T p.V266= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV52584100; called by muse, mutect2
- ZNF646 | c.5286C>T p.T1762= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV54926665; called by mutect2, varscan2
